Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7446, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7446-01A (Primary Tumor).

[page 1 of 3]
SUPPLEMENTAL REPORT

(C) LEFT MODIFIED NECK DISSECTION, TOTAL THYROIDECTOMY, SUPERIOR MEDIASTINAL DISSECTION, PARTIAL DISSECTION, CLAVICLE, FIRST RIB:

Sections of bone tissue submitted for decalcification appear free of tumor.

DIAGNOSIS

(A) LEFT PARTIAL GLOSSECTOMY AND PHARYNGECTOMY:

INVASIVE, MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

Focal perineural invasion present.

All margins free of tumor.

(B) LEFT CHEEK:

Epidermal inclusion cyst, keratinous type.

(C) LEFT MODIFIED NECK DISSECTION, TOTAL THYROIDECTOMY, SUPERIOR MEDIASTINAL DISSECTION, PARTIAL RESECTION, CLAVICLE, FIRST RIB:

METASTATIC, MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA IN SOFT TISSUE.

Soft tissue margins are free of tumor. (See comment)

Thyroid with colloid nodule, no tumor present.

Skin with solar elastosis, no tumor present.

METASTATIC SQUAMOUS CELL CARCINOMA PRESENT IN 1 OF 2 LYMPH NODES.

(D) CYST OF MANDIBLE:

Cyst with hemorrhage and fibrosis, no tumor present.

(E) TOOTH:

Gross examination only.

Entire report and diagnosis completed by:

Report released by:

COMMENT

Bone is submitted for decalcification and a supplemental report will be issued after microscopic examination.

[page 2 of 3]
GROSS DESCRIPTION

(A) LEFT PARTIAL GLOSSECTOMY AND PHARYNGECTOMY - Tongue (5.0 x 4.0 x 2.0 cm), attached portion of pharyngeal mucosa and soft tissue (1.5 x 1.0 x 1.0 cm).

An irregular ulcero-nodular lesion is present centrally on the tongue surface and measures 2.0 x 1.5 cm on the surface and 1.2 cm in depth. It is located 1.0 cm from the anterior (stitched) resection margin and 0.5 cm from the deep soft, tissue margin. Cut surfaces are gray-white and gritty.

Tissue for flow cytometry and Tumor Bank are given.

INKING CODE: Black-lateral; yellow-medial; green-posterior (pharyngeal).

SECTION CODE: A1-A4, frozen section medial; A5-A7, frozen section lateral; A8, A9, frozen section posterior (pharyngeal); A10, frozen section, deep (base); A11, perpendicular margin, anterior (frozen section); A12, representative section of tumor.

*FS/DX: INVASIVE SQUAMOUS CELL CARCINOMA, ALL MARGINS FREE OF TUMOR.

(B) LEFT CHEEK - Skin fragment (2.5 x 1.5 cm on the surface and 1.0 cm in thickness), a ruptured and partially cut through cyst is present (1.3 cm in greatest dimension) containing keratinous debris.

INKING CODE: Surgical margins-black.

SECTION CODE: B1, frozen section; B2, representative section of the cyst.

*FS/DX: EPIDERMAL INCLUSION CYST.

(C) LEFT MODIFIED NECK DISSECTION, TOTAL THYROIDECTOMY SUPERIOR MEDIASTINAL DISSECTION, PARTIAL RESECTION, CLAVICLE, FIRST RIB - The specimen (10 x 8 x 4 cm) consists of a skin ellipse (10 x 6 cm), thyroid gland (6.5 x 3.5 x 2 cm), sternal bone (7 x 2.5 x 1.3 cm), sterno-clavicular joints with attached portions of clavicular bone (each 2.5 cm in length, 1.5 cm in diameter), and portion of first rib.

Serial sections show a soft tissue mass with irregular borders and gray-white cut surface infiltrating through soft tissue and located 4 and 7 cm from the superior soft tissue resection margin. It extends to the sternal bone but does not infiltrate it. The tumor is located 2 cm from the overlying skin.

Two lymph nodes measuring between 1.5 cm and .5 cm in greatest dimension are identified and all are involved by tumor.

Bone is submitted for decalcification.

INK CODE: black, resection margin.

SECTION CODE: C1, tumor; C2, tumor with superior soft tissue margin; C3, tumor with adjacent soft tissue, red margin lesion; C4 and C5, thyroid; C6, skin; C7, inferior en face soft tissue margin; C8-C10, lymph nodes superior and to the left (C9, bisected); C11, nodular structures on the right superior.

(D) CYST OF MANDIBLE - An irregular membranous gray-white tissue with smooth surface (1.5 x 1.0 x 0.2 cm) all submitted as D.

(E) TOOTH (GROSS ONLY) - Multile irregular gray-white fragments of tooth measuring 1.0 x 0.7 x 0.5 cm in aggregate. Gross examination only.

SNOMED CODES

M-80703 M-80706 T-53000 T-C4200

Source: NCI Genomic Data Commons file 746b4a4f-ab58-4fb2-939d-75ca75297ce3 (TCGA-CV-7446.FC2E5F98-7FAD-46B6-A61C-4B6AEDE1CDEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).